Somatic mutation profile of tumor specimen MP2PRT-PAPTNI-TMP1-A (aliquot MP2PRT-PAPTNI-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PAPTNI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,095 days).
Specimen MP2PRT-PAPTNI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 285d6f00-6d72-48d6-a420-f33561b7ddde.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPTNI-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPTNI-NM1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5bc1579-75e1-40ed-8919-9075d90e67cc

The open-access MAF lists 34 somatic variants for this specimen: 24 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 9, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 38/447 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 109/424 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS10 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 50/572 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.232); catalogued as rs782280501, COSV54357772, COSV99547267; called by muse, mutect2
- ARSH | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 101/595 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs754643657; called by muse, mutect2, varscan2
- GFRA3 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 106/538 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs573286530; called by muse, mutect2, varscan2
- INPP5K | c.32G>A p.G11D | Missense Mutation (SNP) | VAF 121/814 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs766695932; called by muse, mutect2, varscan2
- LRRC45 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 26/484 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs542227613; called by muse, mutect2
- MYH13 | c.4691G>A p.R1564H | Missense Mutation (SNP) | VAF 65/506 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.192); catalogued as rs367901073, COSV52831274; called by muse, mutect2, varscan2
- OR11H1 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 84/577 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as rs560715664; called by muse, mutect2, varscan2
- PDZRN3 | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 121/531 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as rs762027539, COSV55202644; called by muse, mutect2, varscan2
- PFDN6 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 81/598 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs202091465; called by muse, mutect2, varscan2
- PKD1L3 | c.2032G>A p.V678M | Missense Mutation (SNP) | VAF 44/520 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); catalogued as rs139878577; called by muse, mutect2
- PTPRS | c.1291C>T p.R431W | Missense Mutation (SNP) | VAF 36/774 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1237664443, COSV53621524; called by muse, mutect2
- TENM2 | c.3181G>A p.E1061K (on ENST00000518659 / NM_001122679.2; = p.E829K on NM_001080428.3) | Missense Mutation (SNP) | VAF 21/263 reads (8%) | SIFT tolerated (0.76); PolyPhen benign (0.015); catalogued as rs1464106409, COSV69133110; called by muse, mutect2
- APOB | c.233G>T p.C78F | Missense Mutation (SNP) | VAF 60/278 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); called by mutect2, varscan2
- CNTN5 | c.980+1del p.X327_splice | Splice Site (DEL) | VAF 34/176 reads (19%) | called by mutect2, pindel, varscan2
- DNAH7 | c.10427A>G p.E3476G | Missense Mutation (SNP) | VAF 51/399 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- FSIP2 | c.2171C>A p.P724H | Missense Mutation (SNP) | VAF 67/278 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMX2 | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 36/1496 reads (2%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.675); called by muse, mutect2
- MROH7 | c.2478G>T p.K826N | Missense Mutation (SNP) | VAF 45/575 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.57); called by muse, mutect2
- MYH8 | c.3018C>A p.H1006Q | Missense Mutation (SNP) | VAF 22/781 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.041); called by muse, mutect2
- SACS | c.9695C>T p.T3232I | Missense Mutation (SNP) | VAF 149/292 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- UGT1A4 | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 30/512 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.057); called by muse, mutect2
- USP29 | c.2419G>T p.A807S | Missense Mutation (SNP) | VAF 19/502 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.172); called by muse, mutect2
- CCDC27 | c.1398G>A p.T466= | Silent (SNP) | VAF 38/302 reads (13%) | catalogued as rs746902221, COSV53902757; called by muse, mutect2, varscan2
- CLVS1 | c.510C>T p.I170= | Silent (SNP) | VAF 79/332 reads (24%) | catalogued as rs746041983, COSV57971952; called by muse, mutect2, varscan2
- MOXD1 | c.909C>T p.L303= | Silent (SNP) | VAF 24/472 reads (5%) | called by muse, mutect2
- NPAS2 | c.735C>T p.D245= | Silent (SNP) | VAF 40/197 reads (20%) | catalogued as rs763776277, COSV100176839; called by muse, mutect2, varscan2
- OR14J1 | c.771T>C p.F257= | Silent (SNP) | VAF 19/474 reads (4%) | catalogued as rs748835504; called by muse, mutect2
- PCDH15 | c.4497C>T p.D1499= | Silent (SNP) | VAF 24/501 reads (5%) | catalogued as rs376485360; called by muse, mutect2
- SSTR2 | c.84C>A p.T28= | Silent (SNP) | VAF 40/652 reads (6%) | called by muse, mutect2
- STRN4 | c.2232C>T p.G744= | Silent (SNP) | VAF 38/530 reads (7%) | catalogued as rs747722239; called by muse, mutect2
- UMOD | c.147G>A p.T49= | Silent (SNP) | VAF 117/482 reads (24%) | catalogued as rs745594856, COSV56775382; called by muse, mutect2, varscan2
- PDLIM3 | c.162-1870C>T | Intron (SNP) | VAF 31/635 reads (5%) | catalogued as rs769851440, COSV52977875; called by muse, mutect2
